Somatic mutation profile of tumor specimen TCGA-A6-6137-01A (aliquot TCGA-A6-6137-01A-11D-1771-10) from TCGA case TCGA-A6-6137, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Ascending colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 55.0 years (20,095 days).
Specimen TCGA-A6-6137-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 838c8889-dfcd-4640-a5b9-b3d0b286f3ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-6137-10A (Blood Derived Normal), aliquot TCGA-A6-6137-10A-01D-1806-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e434f58d-ee62-47d2-9590-602fe1e66baa

The open-access MAF lists 124 somatic variants for this specimen: 98 protein-altering or splice-affecting, 23 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 23, Nonsense Mutation 8, Frame Shift Ins 3, RNA 3, In Frame Del 2, Splice Site 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 69/84 reads (82%) | catalogued as rs137852217, CM090019, COSV57654223; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.1495C>T p.R499* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | hotspot (GDC flag); catalogued as rs137854580, CM930023, COSV57322064; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.3220G>A p.G1074S | Missense Mutation (SNP) | VAF 40/350 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs587779554, CM1412698, COSV58584727; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1435C>T p.R479* (on ENST00000281708 / NM_001349798.2; = p.R399* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 16/75 reads (21%) | hotspot (GDC flag); catalogued as COSV55894141, COSV55894999, COSV55908957; called by muse, mutect2, varscan2
- TP53 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 21/41 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA9 | c.2797C>G p.L933V | Missense Mutation (SNP) | VAF 19/280 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.251); catalogued as COSV100383134; called by muse, mutect2
- ABCA9 | c.1615+1G>C p.X539_splice | Splice Site (SNP) | VAF 10/84 reads (12%) | catalogued as COSV100383216, COSV60622389; called by muse, mutect2, varscan2
- ADAM18 | c.2203G>A p.D735N | Missense Mutation (SNP) | VAF 26/260 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs184662370, COSV55843220; called by muse, mutect2, varscan2
- ADGRD1 | c.1871G>A p.R624H | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs529404381, COSV55441481, COSV99897087; called by muse, mutect2, varscan2
- AHCTF1 | c.1682T>C p.L561P (on ENST00000366508; = p.L535P on NM_015446.5) | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100403766; called by muse, mutect2
- APC | c.4351G>T p.E1451* | Nonsense Mutation (SNP) | VAF 27/80 reads (34%) | catalogued as CM010759, COSV57351757, COSV57354939; called by muse, mutect2, varscan2
- ARID2 | c.1277C>T p.T426M | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV57596651, COSV57609951; called by muse, mutect2, varscan2
- ATAD1 | c.37C>T p.R13W | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100058227, COSV57757321; called by muse, mutect2, varscan2
- B3GLCT | c.1382C>T p.S461L | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58454166; called by muse, mutect2, varscan2
- BOD1L1 | c.5281G>C p.V1761L | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV50008496; called by muse, mutect2
- C1orf141 | c.562A>T p.I188L | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV63992356; called by muse, mutect2, varscan2
- CADM1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.641); catalogued as COSV59006072; called by muse, mutect2, varscan2
- CCNL2 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.426); catalogued as COSV61224081; called by muse, mutect2, varscan2
- CDK12 | c.2921C>T p.P974L | Missense Mutation (SNP) | VAF 23/316 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1212731319, COSV101420215; called by muse, mutect2
- CHGA | c.790G>T p.E264* | Nonsense Mutation (SNP) | VAF 8/92 reads (9%) | catalogued as COSV53662744, COSV99380964; called by muse, mutect2
- CNOT9 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs1384270952, COSV55299439; called by muse, mutect2, varscan2
- COL1A2 | c.2905G>A p.V969M | Missense Mutation (SNP) | VAF 18/139 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.076); catalogued as rs765448220, COSV51955294; called by muse, mutect2, varscan2
- CSMD2 | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as rs761180145, COSV53892340; called by muse, mutect2, varscan2
- CTR9 | c.2880_2882del p.R962del | In Frame Del (DEL) | VAF 17/71 reads (24%) | catalogued as rs968571283; called by pindel, varscan2
- EFL1 | c.2902G>A p.A968T | Missense Mutation (SNP) | VAF 22/186 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs377682013; called by muse, mutect2, varscan2
- FABP2 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.179); catalogued as COSV56788293; called by muse, mutect2, varscan2
- FAT4 | c.2602G>T p.A868S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV101272361; called by muse, mutect2, varscan2
- FHOD3 | c.1015C>T p.R339W | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs199822186, COSV99941207; called by muse, mutect2, varscan2
- FLG | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 60/346 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.969); catalogued as rs376977047, COSV100910407; called by muse, mutect2, varscan2
- FLNC | c.8129G>A p.W2710* | Nonsense Mutation (SNP) | VAF 16/94 reads (17%) | catalogued as COSV50799999; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1575G>T p.L525F | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.602); catalogued as rs1370592602, COSV58549038; called by muse, mutect2, varscan2
- GK2 | c.418A>C p.K140Q | Missense Mutation (SNP) | VAF 22/226 reads (10%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.616); catalogued as COSV100726028, COSV62626329; called by muse, mutect2
- GRIK2 | c.2347C>G p.L783V | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV59710604; called by muse, mutect2
- HAND1 | c.424T>G p.Y142D | Missense Mutation (SNP) | VAF 44/171 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50562423; called by muse, mutect2, varscan2
- HOXD4 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV100106913, COSV60459563; called by muse, mutect2, varscan2
- IGHG1 | c.604T>C p.Y202H | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs749070103; called by muse, mutect2, varscan2
- KCNJ4 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.759); catalogued as rs1213024759, COSV57856448, COSV57856522; called by muse, mutect2, varscan2
- KCNQ5 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59654026; called by muse, mutect2, varscan2
- KCTD8 | c.1342A>T p.K448* | Nonsense Mutation (SNP) | VAF 40/156 reads (26%) | catalogued as rs1185092466, COSV63587017, COSV63595051; called by muse, mutect2, varscan2
- LHX2 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.939); catalogued as COSV65317956; called by muse, mutect2, varscan2
- LIMD1 | c.1729G>A p.V577M | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs751216668, COSV56266420; called by muse, mutect2
- LRP1B | c.2464G>A p.D822N | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); catalogued as rs186583868; called by muse, mutect2, varscan2
- LRRC4 | c.1169C>T p.T390I | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99975012; called by muse, mutect2, varscan2
- LRRK2 | c.2946A>T p.E982D | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV54148087; called by muse, mutect2, varscan2
- MAN1C1 | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV56042940; called by muse, mutect2, varscan2
- MARCHF4 | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56103875; called by muse, mutect2, varscan2
- MBD4 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs755035506, COSV99959360; called by muse, mutect2
- METAP1D | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); catalogued as rs138526406; called by muse, mutect2, varscan2
- MTX3 | c.186G>A p.M62I | Missense Mutation (SNP) | VAF 37/305 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV72512206, COSV72512344; called by muse, mutect2, varscan2
- NID2 | c.3448G>A p.D1150N | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as rs1487000732, COSV53496464, COSV53499694; called by muse, mutect2, varscan2
- NRXN2 | c.2398C>T p.R800C | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1451669556, COSV55450180; called by muse, mutect2, varscan2
- OR51S1 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV59057812; called by muse, mutect2, varscan2
- OR5M3 | c.210G>C p.W70C | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56566175; called by muse, mutect2, varscan2
- OTOP1 | c.961G>A p.V321M | Missense Mutation (SNP) | VAF 17/102 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs140788465; called by muse, mutect2, varscan2
- PABPN1L | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs774478649, COSV56351230; called by muse, mutect2, varscan2
- PCDH18 | c.3245C>T p.S1082F | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.459); catalogued as COSV61268579; called by muse, mutect2
- PCDHA7 | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV65343037; called by muse, mutect2
- PCDHB2 | c.754C>A p.Q252K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.02); catalogued as COSV99523200; called by muse, mutect2, varscan2
- PCDHGA7 | c.1654G>A p.V552M | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.852); catalogued as rs756336021, COSV53918962, COSV53956234; called by muse, mutect2, varscan2
- PITPNM2 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs201145774; called by muse, mutect2, varscan2
- PITPNM3 | c.2125G>T p.V709F | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.141); catalogued as rs762622549, COSV52593921; called by muse, mutect2, varscan2
- PMS1 | c.1577G>A p.C526Y | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0.071); catalogued as COSV59715444; called by muse, mutect2, varscan2
- POU3F4 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.642); catalogued as rs1279423686, COSV64538200; called by muse, mutect2
- PPFIA4 | c.1240C>T p.R414C (on ENST00000447715; = p.R410C on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs534168322, COSV99690601; called by muse, mutect2, varscan2
- PPM1J | c.1436G>A p.R479H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs113935705; called by muse, mutect2, varscan2
- PRSS12 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs367921225; called by muse, mutect2
- PTCHD3 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.63); PolyPhen benign (0.031); catalogued as rs1344898405, COSV71256255; called by muse, mutect2, varscan2
- RAB11FIP1 | c.3551C>A p.A1184E (on ENST00000330843 / NM_001002814.3; = p.A550E on NM_025151.5) | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV54758961; called by muse, mutect2, varscan2
- RBM42 | c.167T>C p.I56T | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.438); catalogued as COSV52547256; called by muse, mutect2, varscan2
- RGL3 | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV66507276; called by muse, mutect2, varscan2
- RHOBTB3 | c.1366G>A p.A456T | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.076); catalogued as COSV66101436; called by muse, mutect2
- SCARA3 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.153); catalogued as rs146536900; called by muse, mutect2, varscan2
- SCN2A | c.4912C>T p.R1638C | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV51836220; called by muse, mutect2, varscan2
- SCN3B | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV54798748; called by muse, mutect2, varscan2
- SELP | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.233); catalogued as COSV55249873; called by muse, mutect2, varscan2
- SLC15A1 | c.1933C>T p.Q645* | Nonsense Mutation (SNP) | VAF 36/80 reads (45%) | catalogued as COSV64730515; called by muse, mutect2, varscan2
- SLC7A1 | c.779C>T p.A260V | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV66329697; called by muse, mutect2, varscan2
- STON1 | c.1397G>A p.R466Q | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.552); catalogued as rs771873180, COSV59128189; called by muse, mutect2
- TEX15 | c.3445G>A p.V1149I (on ENST00000256246; = p.V1532I on NM_001350162.2) | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs758485395, COSV56343702; called by muse, mutect2, varscan2
- TFEC | c.515+1G>A p.X172_splice | Splice Site (SNP) | VAF 27/140 reads (19%) | catalogued as rs1377961775, COSV55398914; called by muse, mutect2, varscan2
- TMEM132D | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs751041490, COSV70594645; called by muse, mutect2, varscan2
- TMPRSS11B | c.499A>G p.T167A | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV60291697; called by muse, mutect2, varscan2
- TOGARAM2 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.076); catalogued as rs778526105, COSV65420477; called by muse, mutect2, varscan2
- TRIM60 | c.311T>G p.L104R | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV61970095; called by muse, mutect2, varscan2
- TTN | c.7430A>T p.K2477M (on ENST00000591111; = p.K2431M on NM_003319.4) | Missense Mutation (SNP) | VAF 24/188 reads (13%) | PolyPhen probably damaging (0.999); catalogued as COSV59954946; called by muse, mutect2
- VN1R2 | c.1160G>A p.R387Q | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs199981144, COSV59037590, COSV59040122; called by muse, mutect2, varscan2
- WDR37 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs139912371; called by muse, mutect2, varscan2
- ZNF107 | c.1613A>G p.H538R | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100788395; called by muse, mutect2, varscan2
- ZNF417 | c.1433G>A p.C478Y | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs1252282084, COSV56307814; called by muse, mutect2, varscan2
- ZNF438 | c.1090C>G p.P364A | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59193337; called by muse, mutect2, varscan2
- ZNF595 | c.39C>A p.F13L | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV100227708, COSV59552251; called by muse, mutect2
- ZNF667 | c.13C>T p.R5W | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs202093161, COSV52630823, COSV52631642; called by mutect2, varscan2
- AADACL4 | c.1149dup p.D384* | Frame Shift Ins (INS) | VAF 9/62 reads (15%) | called by mutect2, pindel, varscan2
- EPPIN | c.65del p.P22Lfs*3 | Frame Shift Del (DEL) | VAF 21/54 reads (39%) | called by mutect2, pindel, varscan2
- MDGA2 | c.1172dup p.S392Vfs*25 (on ENST00000399232 / NM_001113498.2; = p.S94Vfs*25 on NM_182830.4) | Frame Shift Ins (INS) | VAF 39/241 reads (16%) | called by mutect2, pindel, varscan2
- PIK3CA | c.1356_1364del p.E453_L455del | In Frame Del (DEL) | VAF 28/136 reads (21%) | called by mutect2, pindel, varscan2
- TRIM33 | c.1143dup p.Q382Tfs*20 | Frame Shift Ins (INS) | VAF 23/212 reads (11%) | called by mutect2, pindel, varscan2
- VSIG10 | c.327_337del p.T110Pfs*14 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- AP2B1 | c.2451C>T p.S817= | Silent (SNP) | VAF 70/160 reads (44%) | called by muse, mutect2, varscan2
- ATP10A | c.2004C>T p.N668= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs890489585, COSV63513674; called by muse, mutect2, varscan2
- CDC14A | c.234A>G p.R78= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV60556396; called by muse, mutect2, varscan2
- COL12A1 | c.6630G>T p.L2210= | Silent (SNP) | VAF 21/78 reads (27%) | catalogued as COSV59392234; called by muse, mutect2, varscan2
- ERI1 | c.291A>G p.G97= | Silent (SNP) | VAF 15/30 reads (50%) | catalogued as COSV99141341; called by muse, mutect2, varscan2
- FAM222A | c.141C>T p.D47= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs556069072, COSV62723789, COSV62724207; called by mutect2, varscan2
- HSPB8 | c.126C>T p.D42= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as rs763658767, COSV56137264; called by muse, mutect2, varscan2
- HYDIN | c.5862C>A p.I1954= | Silent (SNP) | VAF 15/83 reads (18%) | called by muse, mutect2
- IL1RL2 | c.873G>A p.R291= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV51814108; called by mutect2, varscan2
- JHY | c.636G>A p.E212= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs772936647, COSV56218491; called by muse, mutect2, varscan2
- LIFR | c.3180A>G p.P1060= | Silent (SNP) | VAF 10/89 reads (11%) | catalogued as rs762094729, COSV54686858; called by mutect2, varscan2
- MUC16 | c.18699T>G p.P6233= | Silent (SNP) | VAF 44/138 reads (32%) | catalogued as COSV67454664; called by muse, mutect2, varscan2
- NPHP1 | c.690G>A p.A230= | Silent (SNP) | VAF 20/204 reads (10%) | catalogued as rs775869913, COSV57206766, COSV57210470; ClinVar: likely benign; called by muse, mutect2
- PPP2R1A | c.666G>A p.L222= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV59043266; called by muse, mutect2, varscan2
- PSG7 | c.894C>T p.P298= | Silent (SNP) | VAF 8/66 reads (12%) | catalogued as COSV101343251; called by muse, mutect2, varscan2
- PTGR1 | c.369C>T p.G123= | Silent (SNP) | VAF 14/130 reads (11%) | catalogued as COSV53027984; called by muse, mutect2
- RNF123 | c.1656G>A p.E552= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV59685528; called by muse, mutect2, varscan2
- SPTBN5 | c.8743C>T p.L2915= | Silent (SNP) | VAF 25/101 reads (25%) | catalogued as COSV58018470; called by muse, mutect2, varscan2
- SPTBN5 | c.7404C>T p.A2468= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV58018482; called by muse, mutect2, varscan2
- TACR1 | c.564G>A p.P188= | Silent (SNP) | VAF 17/152 reads (11%) | catalogued as rs199842504, COSV59480259; called by muse, mutect2, varscan2
- TCHHL1 | c.81A>C p.T27= | Silent (SNP) | VAF 44/135 reads (33%) | catalogued as COSV64285241; called by muse, mutect2, varscan2
- TEP1 | c.5523C>T p.P1841= | Silent (SNP) | VAF 14/62 reads (23%) | catalogued as rs762759586, COSV52990008; called by muse, mutect2, varscan2
- ZNF148 | c.879C>A p.G293= | Silent (SNP) | VAF 91/313 reads (29%) | catalogued as COSV62303001; called by muse, mutect2, varscan2
- AL136982.4 | n.1648G>A | RNA (SNP) | VAF 26/123 reads (21%) | called by muse, mutect2, varscan2
- LRP5L | n.307C>T | RNA (SNP) | VAF 15/159 reads (9%) | catalogued as COSV68602004; called by muse, mutect2
- MIR19B1 | n.8_9del | RNA (DEL) | VAF 29/143 reads (20%) | called by mutect2, pindel, varscan2
